Somatic mutation profile of tumor specimen TCGA-B2-5633-01B (aliquot TCGA-B2-5633-01B-04D-A270-10) from TCGA case TCGA-B2-5633, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 56.1 years (20,493 days).
Specimen TCGA-B2-5633-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe006578-1df7-4fdd-9696-02c779538ea7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-5633-10A (Blood Derived Normal), aliquot TCGA-B2-5633-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c893f82d-ea77-4bbb-a765-ec6da0449d3a

The open-access MAF lists 52 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 13, Nonsense Mutation 3, Intron 2, Frame Shift Del 1, Splice Site 1, Nonstop Mutation 1, Splice Region 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAMP | c.121+2T>C p.X41_splice | Splice Site (SNP) | VAF 24/196 reads (12%) | catalogued as COSV99297902; called by muse, mutect2, varscan2
- ATP13A5 | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV60873395; called by muse, mutect2, varscan2
- ATP2A3 | c.2496G>C p.W832C | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99989084; called by muse, mutect2, varscan2
- CENPW | c.188G>C p.C63S | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100851374, COSV64177147; called by muse, mutect2, varscan2
- CHFR | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57177121, COSV99905302; called by muse, mutect2, varscan2
- DHX36 | c.1223T>A p.V408D | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57671391, COSV57676035; called by muse, mutect2, varscan2
- DNM3 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs371617456, COSV62464646; called by muse, mutect2, varscan2
- FARP1 | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as COSV60336606, COSV60344986; called by muse, mutect2, varscan2
- GAP43 | c.142A>G p.R48G | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1311063650, COSV59347350; called by muse, varscan2
- GON4L | c.6068T>C p.V2023A | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV99674109; called by muse, mutect2, varscan2
- KMT2C | c.8887C>T p.R2963C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs187761353, COSV51484732; called by muse, mutect2, varscan2
- LAMA3 | c.3079G>A p.A1027T | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.92); catalogued as COSV58076230; called by muse, mutect2, varscan2
- LARP1 | c.2533A>T p.T845S (on ENST00000518297 / NM_033551.3; = p.T768S on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.145); catalogued as COSV60430307; called by muse, mutect2, varscan2
- LRWD1 | c.898T>A p.F300I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52961755; called by muse, mutect2, varscan2
- NFAT5 | c.2212T>A p.S738T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV63031099; called by muse, mutect2, varscan2
- NFAT5 | c.2213C>A p.S738* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | catalogued as COSV63031111; called by muse, mutect2, varscan2
- NMUR2 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.207); catalogued as rs1326243803, COSV54917555, COSV99677224; called by muse, mutect2, varscan2
- OR2A4 | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs761209612, COSV59576228; called by muse, mutect2, varscan2
- OR52A5 | c.951A>G p.*317Wext*9 | Nonstop Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV56616363; called by muse, mutect2, varscan2
- PACSIN2 | c.225G>C p.Q75H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54322324, COSV99606227; called by muse, mutect2, varscan2
- PLK4 | c.2381G>A p.R794K | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs752630935; called by muse, mutect2
- RASSF2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as rs748168721, COSV65082559; called by muse, mutect2, varscan2
- RBM39 | c.112A>G p.S38G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV53615420; called by muse, varscan2
- ROS1 | c.6922G>C p.E2308Q | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV63855497, COSV63860020; called by muse, mutect2, varscan2
- SEMA3G | c.1515G>A p.M505I | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV51597672; called by muse, mutect2, varscan2
- SPDL1 | c.1377T>A p.D459E | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.816); catalogued as COSV54669266; called by muse, mutect2, varscan2
- TEAD2 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs369344041; called by muse, mutect2, varscan2
- TLR10 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV58301773; called by muse, mutect2, varscan2
- TNS1 | c.1469G>C p.G490A | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV50747126; called by muse, mutect2, varscan2
- TOP1 | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63695584; called by muse, mutect2, varscan2
- UBIAD1 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65148118; called by muse, mutect2, varscan2
- WDFY3 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 68/307 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs201745590, COSV55710898; called by muse, mutect2, varscan2
- CAMKK1 | c.1215G>A p.L405= | Splice Region (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- CDK12 | c.4283_4284insAAA p.S1427_N1428insK (on ENST00000447079 / NM_016507.4; = p.S1418_N1419insK on NM_015083.3) | In Frame Ins (INS) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- IL18RAP | c.1265del p.S422Mfs*7 | Frame Shift Del (DEL) | VAF 11/82 reads (13%) | called by mutect2, pindel, varscan2
- NRIP1 | c.1893dup p.Q632Tfs*30 | Frame Shift Ins (INS) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- TMTC1 | c.2101G>C p.E701Q (on ENST00000539277 / NM_001193451.2; = p.E593Q on NM_175861.3) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- FAM114A2 | c.1428C>G p.L476= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV61078538; called by muse, mutect2, varscan2
- FASN | c.5886T>A p.L1962= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100147697; called by muse, mutect2, varscan2
- H4-16 | c.225G>A p.E75= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV63762454; called by muse, mutect2, varscan2
- IARS2 | c.2679C>T p.I893= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as rs113314730, COSV56962955; called by muse, mutect2, varscan2
- IGSF22 | c.1197C>T p.F399= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV60032425, COSV60037419; called by muse, mutect2, varscan2
- NEU3 | c.927A>T p.P309= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs766760875, COSV53638415; called by muse, mutect2, varscan2
- OSR1 | c.195G>A p.P65= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs1248800793, COSV55345569; called by muse, mutect2
- PCDHGA10 | c.948C>T p.T316= | Silent (SNP) | VAF 6/156 reads (4%) | catalogued as rs1328389134, COSV99549502; called by muse, mutect2
- SHROOM4 | c.30C>T p.Y10= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as COSV56795256; called by muse, mutect2, varscan2
- SLC15A3 | c.1026T>G p.L342= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV50017394; called by muse, mutect2, varscan2
- SLC35D1 | c.846T>G p.A282= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV52432776; called by muse, mutect2, varscan2
- SOBP | c.2559G>C p.G853= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV57999269; called by muse, mutect2, varscan2
- ZC3H7B | c.1548G>A p.R516= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV60964064; called by muse, mutect2, varscan2
- JMJD1C | c.333+7312G>C | Intron (SNP) | VAF 17/68 reads (25%) | catalogued as COSV67866238; called by muse, mutect2, varscan2
- KIF1B | c.2115+7264T>C | Intron (SNP) | VAF 36/144 reads (25%) | catalogued as COSV55813901; called by muse, mutect2, varscan2
